MMRF case MMRF_1980 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e9df379b-d852-49ee-8250-303024c2ab8e

Demographics
Sex at birth: male; Race: other; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.2 years (24,529 days); ISS stage: I; Days to last known disease status: 1,007 days (2.8 years); Days to last follow up: 1,007 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,007.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 120 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 6.65 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.59 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 84 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.93 mg/dL; Hemoglobin 6.01 mmol/L; Leukocytes 6.42 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.93 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 10.8 mmol/L.
- Day 166 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Hemoglobin 6.39 mmol/L; Leukocytes 7.22 ×10⁹/L; Absolute Neutrophil 4.22 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 12.8 mmol/L.
- Day 278 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.98 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 5.63 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.98 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 11.8 mmol/L.
- Day 335 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Hemoglobin 6.2 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 1.95 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 442: Serum Free Immunoglobulin Light Chain, Kappa 8.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 8.79 ×10⁹/L; Absolute Neutrophil 5.89 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 8.03 mmol/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 8.84 ×10⁹/L; Absolute Neutrophil 4.81 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.
- Day 635 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.85 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 4.87 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 1.83 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 8.36 mmol/L.
- Day 714 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Beta 2 Microglobulin 2.46 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 798 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.37 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 6.49 mmol/L.
- Day 901 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 138 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.3 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 6.42 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 12.4 mmol/L.

Other clinical attributes
- Day 0: Weight: 65 kg; Height: 154 cm.

Biospecimens (2 samples)
- Sample MMRF_1980_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1980_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
